Somatic mutation profile of tumor specimen 0DS531 from CCDI case PBCHAS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pineoblastoma; Tissue or organ of origin: Pineal gland; Age at diagnosis: 3.2 years (1,159 days).
Specimen 0DS531: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54fe9430-ee88-49e7-b07d-b652c75bf5b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS540 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1156a3c3-d583-4854-a26b-89ade7073ccd

The open-access MAF lists 24 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, 3'UTR 3, Intron 3, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFM | c.775G>C p.V259L | Missense Mutation (SNP) | VAF 26/544 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767963481; called by muse, mutect2
- CNOT6L | c.49C>G p.R17G (on ENST00000504123 / NM_001286790.2; = p.R12G on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/374 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV99362116; called by muse, mutect2, varscan2
- GLIPR1 | c.794T>C p.L265S | Missense Mutation (SNP) | VAF 65/460 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs749751352; called by muse, mutect2, varscan2
- PLD2 | c.2158C>T p.R720C | Missense Mutation (SNP) | VAF 58/355 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs537960609; called by muse, mutect2
- EOGT | c.404G>C p.C135S | Missense Mutation (SNP) | VAF 16/430 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FOXH1 | c.418T>G p.F140V | Missense Mutation (SNP) | VAF 348/602 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- GNAI1 | c.270G>T p.R90S | Missense Mutation (SNP) | VAF 28/525 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2
- KALRN | c.8623A>T p.S2875C (on ENST00000360013 / NM_001024660.4; = p.S1178C on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/244 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PKD1L1 | c.2485C>G p.P829A | Missense Mutation (SNP) | VAF 55/451 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- PURG | c.627A>G p.I209M | Missense Mutation (SNP) | VAF 36/500 reads (7%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.01); called by muse, mutect2
- UGP2 | c.928G>T p.V310L | Missense Mutation (SNP) | VAF 170/669 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- UNC5B | c.454C>G p.R152G | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2
- EPPK1 | c.4771C>T p.L1591= | Silent (SNP) | VAF 27/587 reads (5%) | called by muse, mutect2
- FPGT-TNNI3K | c.1617T>C p.Y539= | Silent (SNP) | VAF 25/172 reads (15%) | called by muse, mutect2
- LRRC15 | c.1341G>A p.T447= | Silent (SNP) | VAF 103/431 reads (24%) | catalogued as rs746697817; called by muse, mutect2, varscan2
- SAPCD2 | c.600G>C p.A200= | Silent (SNP) | VAF 145/345 reads (42%) | called by muse, mutect2, varscan2
- ACADVL | c.1434+36A>T | Intron (SNP) | VAF 52/211 reads (25%) | called by muse, mutect2, varscan2
- ANLN | c.*10T>C | 3'UTR (SNP) | VAF 171/351 reads (49%) | called by muse, mutect2, varscan2
- CAMK4 | c.-65G>A | 5'UTR (SNP) | VAF 20/113 reads (18%) | called by muse, mutect2, varscan2
- CENATAC | c.579-22C>A | Intron (SNP) | VAF 8/146 reads (5%) | catalogued as rs1401810924; called by muse, mutect2
- GREM2 | c.*34G>A | 3'UTR (SNP) | VAF 9/129 reads (7%) | catalogued as rs1445072004; called by muse, mutect2
- OR4K17 | c.*28C>A | 3'UTR (SNP) | VAF 58/259 reads (22%) | catalogued as rs1207880599; called by muse, mutect2
- PCSK6 | c.2700-16C>T | Intron (SNP) | VAF 66/337 reads (20%) | catalogued as rs765579645; called by muse, mutect2, varscan2
- SPATA31C1 | n.585T>C | RNA (SNP) | VAF 144/691 reads (21%) | called by muse, mutect2, varscan2
